Somatic mutation profile of tumor specimen MMRF_2297_1_BM_CD138pos (aliquot MMRF_2297_1_BM_CD138pos_T1_KHS5U_K14001) from MMRF case MMRF_2297, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.2 years (21,262 days).
Specimen MMRF_2297_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d8aeefe-7836-4d16-a736-1f384acb216c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2297_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2297_1_PB_Whole_C1_KHS5U_K14000; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f0c319f-c794-4996-bcf4-bab2eb40bfe9

The open-access MAF lists 87 somatic variants for this specimen: 32 protein-altering or splice-affecting, 11 silent, 44 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, 3'UTR 26, Silent 11, Intron 10, 5'UTR 3, 5'Flank 3, RNA 2, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.1436A>G p.D479G | Missense Mutation (SNP) | VAF 15/118 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705800, COSV66705888; called by muse, mutect2, varscan2
- ADGRB2 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779927149, COSV99926623; called by muse, mutect2
- CUBN | c.10837C>T p.R3613C | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.545); catalogued as rs747501234, COSV64722089; called by muse, mutect2, varscan2
- IGHV2-70 | c.157A>C p.M53L | Missense Mutation (SNP) | VAF 71/145 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs369368857; called by muse, varscan2
- IGLL5 | c.124A>G p.M42V | Missense Mutation (SNP) | VAF 18/18 reads (100%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs550903741, COSV73251065, COSV73251253; called by muse, mutect2, varscan2
- JMJD1C | c.4950C>A p.Y1650* | Nonsense Mutation (SNP) | VAF 38/99 reads (38%) | catalogued as COSV59517794; called by muse, mutect2, varscan2
- KIAA0753 | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 80/204 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs377589510, COSV100810711; called by muse, mutect2, varscan2
- LENG9 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.094); catalogued as COSV56619005; called by muse, mutect2
- NTAQ1 | c.491C>G p.P164R | Missense Mutation (SNP) | VAF 123/328 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99783783; called by muse, mutect2, varscan2
- PELI1 | c.1003A>G p.M335V | Missense Mutation (SNP) | VAF 17/205 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as rs1474368058; called by muse, mutect2
- PRKD2 | c.1711C>T p.R571W | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99353986; called by muse, mutect2, varscan2
- RIPK3 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs534453010; called by muse, mutect2, varscan2
- RRM1 | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs769187910; called by muse, mutect2, varscan2
- SEPTIN4 | c.557G>T p.G186V | Missense Mutation (SNP) | VAF 75/182 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58728107; called by muse, mutect2, varscan2
- TAF1 | c.2450A>G p.H817R (on ENST00000373790 / NM_138923.4; = p.H838R on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52106957; called by muse, mutect2, varscan2
- ATR | c.4972T>C p.F1658L | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- FAM78B | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 151/178 reads (85%) | SIFT tolerated (0.44); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FLI1 | c.11C>T p.T4I | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GPR35 | c.496A>G p.T166A | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.005); called by muse, mutect2
- H2BC11 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- HYDIN | c.10960G>A p.D3654N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.01); called by muse, mutect2
- OR10D3 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 70/140 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- OR10J3 | c.587A>G p.N196S | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.1); called by muse, mutect2
- POPDC2 | c.491+2T>G p.X164_splice | Splice Site (SNP) | VAF 54/94 reads (57%) | called by muse, mutect2, varscan2
- PPP2R1B | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 109/233 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- RPS6KA5 | c.157A>G p.K53E | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- SPEG | c.5603T>A p.L1868Q | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TBC1D19 | c.566T>A p.L189Q | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- TCP10L2 | c.553G>T p.D185Y | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); called by mutect2, varscan2
- TMEM200C | c.82A>C p.K28Q | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- WNT2 | c.717T>A p.N239K | Missense Mutation (SNP) | VAF 25/320 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2
- ZC3H7B | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT tolerated (0.37); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CCDC63 | c.1023G>A p.T341= | Silent (SNP) | VAF 37/81 reads (46%) | catalogued as rs549200490, COSV57527025; called by muse, mutect2, varscan2
- CEP128 | c.1806A>G p.Q602= | Silent (SNP) | VAF 114/242 reads (47%) | called by muse, mutect2, varscan2
- FLG2 | c.6939A>G p.G2313= | Silent (SNP) | VAF 227/347 reads (65%) | called by muse, mutect2, varscan2
- FZD4 | c.1452T>A p.S484= | Silent (SNP) | VAF 221/589 reads (38%) | catalogued as rs1220146427; called by muse, mutect2, varscan2
- IGLV3-1 | c.60C>T p.S20= | Silent (SNP) | VAF 73/77 reads (95%) | catalogued as rs577917177; called by muse, varscan2
- KIF18A | c.2538A>C p.V846= | Silent (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- KRTAP25-1 | c.168A>C p.I56= | Silent (SNP) | VAF 24/310 reads (8%) | catalogued as COSV68914507; called by muse, mutect2
- MROH9 | c.1680T>C p.S560= | Silent (SNP) | VAF 14/214 reads (7%) | called by muse, mutect2
- PTCD1 | c.694C>T p.L232= | Silent (SNP) | VAF 56/143 reads (39%) | called by muse, mutect2, varscan2
- RPS6KL1 | c.1377C>T p.S459= | Silent (SNP) | VAF 288/577 reads (50%) | catalogued as rs35753254; called by muse, mutect2, varscan2
- SYNE1 | c.7609A>C p.R2537= (on ENST00000367255 / NM_182961.4; = p.R2544= on NM_033071.3) | Silent (SNP) | VAF 52/125 reads (42%) | catalogued as rs753449219; called by muse, mutect2, varscan2
- AC079612.1 | n.2172C>T | RNA (SNP) | VAF 124/224 reads (55%) | catalogued as rs954257066; called by muse, mutect2, varscan2
- ACKR2 | c.*1183C>A | 3'UTR (SNP) | VAF 28/68 reads (41%) | called by muse, mutect2, varscan2
- ANXA10 | c.*230A>G | 3'UTR (SNP) | VAF 51/152 reads (34%) | called by muse, mutect2, varscan2
- C7 | c.*986G>T | 3'UTR (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- C9orf57 | c.*610C>T | 3'UTR (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- CBLB | c.*706G>A | 3'UTR (SNP) | VAF 42/84 reads (50%) | called by muse, mutect2, varscan2
- CLDND2 | c.-40C>T | 5'UTR (SNP) | VAF 29/96 reads (30%) | catalogued as rs1247603782; called by muse, mutect2, varscan2
- CNIH1 | c.*525C>T | 3'UTR (SNP) | VAF 19/45 reads (42%) | catalogued as rs934301915; called by muse, mutect2, varscan2
- DCLK3 | c.*1728A>G | 3'UTR (SNP) | VAF 38/106 reads (36%) | called by muse, mutect2, varscan2
- DGKI | chr7:137847067 A>G | 5'Flank (SNP) | VAF 18/59 reads (31%) | called by mutect2, varscan2
- DSG1 | c.*596A>G | 3'UTR (SNP) | VAF 16/89 reads (18%) | called by muse, mutect2, varscan2
- DSTYK | c.*3457C>T | 3'UTR (SNP) | VAF 11/158 reads (7%) | called by muse, mutect2
- EDN2 | c.443+352C>A | Intron (SNP) | VAF 53/124 reads (43%) | called by muse, mutect2, varscan2
- ENSA | c.*479A>G | 3'UTR (SNP) | VAF 147/237 reads (62%) | called by muse, mutect2, varscan2
- EPSTI1 | c.248-106A>G | Intron (SNP) | VAF 15/27 reads (56%) | called by muse, mutect2
- FGFR3 | c.*224_*250del | 3'UTR (DEL) | VAF 28/96 reads (29%) | called by mutect2, pindel, varscan2
- FOXP2 | c.*2325A>G | 3'UTR (SNP) | VAF 49/105 reads (47%) | called by muse, mutect2, varscan2
- FREM2 | c.*1032G>T | 3'UTR (SNP) | VAF 38/52 reads (73%) | called by muse, mutect2, varscan2
- GPC5 | c.*451T>A | 3'UTR (SNP) | VAF 54/69 reads (78%) | called by muse, mutect2, varscan2
- GUCY1A2 | c.*116A>T | 3'UTR (SNP) | VAF 22/57 reads (39%) | catalogued as COSV99973526; called by muse, mutect2, varscan2
- H2AZ1 | c.326-72C>A | Intron (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- H3C8 | c.*98G>A | 3'UTR (SNP) | VAF 6/113 reads (5%) | catalogued as rs1008654454; called by muse, mutect2
- HGF | c.625+775C>A | Intron (SNP) | VAF 41/95 reads (43%) | catalogued as rs1298964225; called by muse, mutect2, varscan2
- HTT | c.*230A>G | 3'UTR (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- KCTD8 | c.*120T>A | 3'UTR (SNP) | VAF 62/184 reads (34%) | called by muse, mutect2, varscan2
- MIPOL1 | c.*4250T>C | 3'UTR (SNP) | VAF 7/108 reads (6%) | called by muse, mutect2
- MIR5195 | chr14:106851340 T>C | 5'Flank (SNP) | VAF 104/204 reads (51%) | catalogued as rs188124295; called by muse, mutect2, varscan2
- NIM1K | c.-200C>A | 5'UTR (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- NKAIN2 | c.*1143C>A | 3'UTR (SNP) | VAF 26/53 reads (49%) | called by muse, mutect2, varscan2
- NPAP1L | n.280C>T | RNA (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- PLEKHA7 | c.87-47C>A | Intron (SNP) | VAF 21/52 reads (40%) | called by muse, mutect2, varscan2
- PRSS45P | c.*52G>A | 3'UTR (SNP) | VAF 44/104 reads (42%) | called by muse, mutect2, varscan2
- PTCHD1 | c.*7622G>A | 3'UTR (SNP) | VAF 36/51 reads (71%) | catalogued as rs1427742831; called by muse, mutect2, varscan2
- PWWP2A | c.584+10237A>G | Intron (SNP) | VAF 188/382 reads (49%) | called by muse, mutect2, varscan2
- RNU6-307P | chr1:174992864 A>G | 5'Flank (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- SLC6A4 | c.*1544G>A | 3'UTR (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- SOCS1 | c.-50-25G>A | Intron (SNP) | VAF 14/26 reads (54%) | catalogued as COSV59658760; called by muse, mutect2
- TCERG1 | c.*417A>T | 3'UTR (SNP) | VAF 4/76 reads (5%) | catalogued as rs1012736223, COSV57033522; called by muse, mutect2
- TRIM2 | c.-49+51236T>C | Intron (SNP) | VAF 66/167 reads (40%) | called by muse, mutect2, varscan2
- TRIM47 | c.772-63A>C | Intron (SNP) | VAF 14/146 reads (10%) | called by muse, mutect2
- TRIM62 | c.-145A>G | 5'UTR (SNP) | VAF 24/55 reads (44%) | catalogued as rs1274766644; called by muse, mutect2, varscan2
- VPS37B | c.111+6298T>A | Intron (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2
- YTHDC1 | c.*1958dup | 3'UTR (INS) | VAF 13/31 reads (42%) | catalogued as rs754675880; called by mutect2, pindel, varscan2
- ZNF260 | c.*3305C>A | 3'UTR (SNP) | VAF 18/52 reads (35%) | called by muse, mutect2, varscan2
